Somatic mutation profile of tumor specimen TCGA-CA-6719-01A (aliquot TCGA-CA-6719-01A-11D-1835-10) from TCGA case TCGA-CA-6719, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.6 years (28,343 days).
Specimen TCGA-CA-6719-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6473ca88-deb7-4476-8107-af5aec46e3ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-6719-10A (Blood Derived Normal), aliquot TCGA-CA-6719-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4f209d8-f263-40a1-89bb-f9c25a2dd0b0

The open-access MAF lists 122 somatic variants for this specimen: 95 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 80, Silent 27, Frame Shift Ins 5, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NR2E3 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775720634, COSV58909153; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRDM14 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs148573764; called by muse, mutect2, varscan2
- SLC19A3 | c.74dup p.S26Lfs*19 | Frame Shift Ins (INS) | VAF 17/84 reads (20%) | catalogued as rs786205213; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 35/56 reads (63%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSS2 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1281210208, COSV53626301, COSV53628841; called by muse, mutect2, varscan2
- ADAMTS16 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as rs756783420, COSV56976962; called by muse, mutect2, varscan2
- AMY1C | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs201967863, COSV64407042; called by muse, mutect2, varscan2
- ANKK1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs771060056, COSV58272467; called by muse, mutect2, varscan2
- ARAP2 | c.4871G>A p.R1624Q | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1249697981, COSV58292022; called by muse, mutect2, varscan2
- BMP7 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275787189, COSV67781628; called by muse, mutect2, varscan2
- C5 | c.2140C>T p.R714* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV56329892; called by muse, mutect2, varscan2
- CACNA1E | c.4972A>T p.R1658W | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV62406505; called by muse, mutect2, varscan2
- CARD6 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as COSV54567515; called by muse, mutect2, varscan2
- CD180 | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as COSV56518975; called by muse, mutect2
- CDH9 | c.1255T>C p.Y419H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99144323; called by muse, mutect2, varscan2
- CHRFAM7A | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772110050, COSV55397071; called by muse, mutect2, varscan2
- CYP7A1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs780668040, COSV56962736; called by muse, mutect2, varscan2
- DKK1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759707601, COSV64760514; called by mutect2, varscan2
- DLD | c.219T>G p.N73K | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99227095; called by muse, mutect2, varscan2
- DNAH5 | c.10735C>A p.Q3579K | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99449393; called by muse, mutect2
- EFHC1 | c.1221dup p.D408Rfs*4 | Frame Shift Ins (INS) | VAF 22/72 reads (31%) | catalogued as rs754483740; ClinVar: uncertain significance; called by mutect2, varscan2
- EHD4 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs150673276; called by muse, mutect2, varscan2
- EPHA4 | c.1466G>C p.R489P | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV56038686; called by muse, mutect2, varscan2
- FAM78B | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as rs754839641, COSV57979913, COSV99070153; called by muse, mutect2, varscan2
- FN1 | c.3718G>A p.G1240S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767515823, COSV60546788; called by muse, mutect2, varscan2
- FNDC1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.449); catalogued as rs781125048, COSV51932111; called by muse, mutect2, varscan2
- FYCO1 | c.3994G>A p.V1332M | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs759599621, COSV56116495; called by muse, mutect2, varscan2
- GANAB | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as rs1201511915, COSV60466773; called by muse, mutect2, varscan2
- GOLGB1 | c.3446C>A p.P1149Q | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV100510769; called by muse, mutect2, varscan2
- GTF2E1 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs570890193, COSV52204000; called by muse, mutect2, varscan2
- H2AC13 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100704372; called by muse, mutect2, varscan2
- HDLBP | c.1698C>A p.C566* | Nonsense Mutation (SNP) | VAF 61/142 reads (43%) | catalogued as COSV100190518; called by muse, mutect2, varscan2
- HELZ2 | c.2006C>T p.A669V (on ENST00000467148 / NM_001037335.2; = p.A100V on NM_033405.3) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1467330063, COSV100915567; called by muse, mutect2
- HTT | c.5834G>A p.R1945Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1044635969, COSV61861446; called by muse, mutect2, varscan2
- IGHE | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs782245796; called by muse, mutect2
- INSR | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1388400190; called by muse, mutect2
- JAK2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.456); catalogued as rs560489093, COSV67637000; called by muse, mutect2, varscan2
- KANK1 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as COSV63213868, COSV63214287; called by muse, mutect2, varscan2
- KAZN | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65722080; called by muse, mutect2, varscan2
- KDM3B | c.532G>T p.V178F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.134); catalogued as COSV58692972; called by muse, mutect2, varscan2
- KDR | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.087); catalogued as rs145458680, COSV55763284; called by muse, mutect2, varscan2
- KLF8 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63848861; called by muse, mutect2
- KRTAP5-10 | c.278dup p.C94Lfs*53 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs774381487; called by mutect2, pindel
- LAMA2 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777327817, COSV69000907; called by muse, mutect2, varscan2
- LILRA4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.34); catalogued as rs1002404506, COSV52490304, COSV52493488; called by muse, mutect2, varscan2
- MICU3 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182707903; called by mutect2, varscan2
- MLH1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750430, CM994601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOG | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781193948, COSV100973007; called by muse, mutect2, varscan2
- MTIF2 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV55052775; called by mutect2, varscan2
- MUC16 | c.25330G>A p.A8444T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.031); catalogued as COSV67447760, COSV67479600; called by muse, mutect2, varscan2
- MYCL | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs775863077, COSV65693552; called by muse, mutect2, varscan2
- NEXN | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53943784; called by muse, mutect2, varscan2
- NT5C2 | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs1141098; called by muse, mutect2, varscan2
- NUAK1 | c.1615G>T p.A539S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV54605761; called by muse, mutect2, varscan2
- PCDHA12 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as rs782526620, COSV56525897; called by muse, mutect2, varscan2
- PCDHAC1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554203972, COSV53853769; called by muse, mutect2, varscan2
- PDIA2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs747106019, COSV51989999; called by muse, mutect2, varscan2
- PRPF40B | c.2206C>T p.R736W (on ENST00000380281; = p.R723W on NM_012272.3) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1462672225, COSV53304952; called by muse, mutect2, varscan2
- PXDNL | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867735607, COSV62493430; called by muse, mutect2
- RAI1 | c.4451C>A p.T1484K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV55395780; called by mutect2, varscan2
- RASA3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as rs370539205; called by muse, mutect2, varscan2
- RCSD1 | c.168del p.K57Rfs*2 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | catalogued as COSV63260330; called by mutect2, pindel, varscan2
- RELL2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs770859414, COSV51838066; called by muse, mutect2, varscan2
- RPP40 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV60292469; called by muse, mutect2, varscan2
- SAMD3 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs371432532, COSV62384765; called by muse, mutect2, varscan2
- SEMA3C | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV54851512; called by muse, mutect2, varscan2
- SLC38A8 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs750398232, COSV55308210; called by muse, mutect2, varscan2
- SNX33 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100145786; called by muse, mutect2, varscan2
- SOAT1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749244142, COSV62655670; called by muse, mutect2, varscan2
- SOX18 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV61110790; called by muse, mutect2, varscan2
- SPTBN1 | c.4532C>T p.T1511M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as rs746665381, COSV61690863; called by muse, mutect2, varscan2
- SUPT20H | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV62248697; called by muse, mutect2, varscan2
- SVEP1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); catalogued as COSV57041782; called by muse, mutect2, varscan2
- TAF1D | c.281del p.K94Rfs*26 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as rs746556335; called by mutect2, varscan2
- TCEAL8 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 69/91 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63506561; called by muse, mutect2, varscan2
- TNR | c.3913C>T p.R1305W | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778628919, COSV54896002, COSV99689299; called by muse, mutect2, varscan2
- TRPC4 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59008143; called by muse, mutect2, varscan2
- TRPS1 | c.1000C>T p.R334C (on ENST00000220888 / NM_001330599.2; = p.R347C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs780212915, COSV55251565, COSV55256742; called by muse, mutect2, varscan2
- TYMS | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV99201051; called by muse, mutect2
- UBE4B | c.2926G>A p.D976N (on ENST00000343090 / NM_001105562.3; = p.D847N on NM_006048.5) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53536719; called by muse, mutect2, varscan2
- USF3 | c.103A>C p.N35H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57075182; called by muse, mutect2, varscan2
- USP25 | c.2999A>G p.H1000R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99583725; called by muse, mutect2
- VGLL3 | c.127-1G>A p.X43_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV67353821; called by muse, mutect2, varscan2
- VPS13B | c.7486C>A p.L2496I | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as COSV62132833; called by muse, mutect2, varscan2
- XK | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 235/270 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1569475561, COSV66120518; called by muse, mutect2, varscan2
- ZBTB32 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.183); catalogued as rs150269464; called by muse, mutect2, varscan2
- ZDHHC5 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99762350, COSV99762648; called by muse, mutect2, varscan2
- ZNF264 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99567229; called by muse, mutect2
- ZNF407 | c.4685C>T p.T1562I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55261146; called by muse, mutect2, varscan2
- ZNF445 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs1339369079, COSV68539270; called by muse, mutect2, varscan2
- ZRANB2 | c.815G>T p.R272I | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.944); catalogued as rs200237539; called by muse, mutect2, varscan2
- CYC1 | c.759dup p.E254Rfs*3 | Frame Shift Ins (INS) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- FRMD7 | c.2006A>C p.E669A | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- GPRIN2 | c.1091del p.P364Qfs*3 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- MED24 | c.2156dup p.E720Gfs*14 | Frame Shift Ins (INS) | VAF 34/92 reads (37%) | called by mutect2, pindel, varscan2
- ALOX5 | c.324C>T p.V108= | Silent (SNP) | VAF 26/30 reads (87%) | catalogued as rs1291125607, COSV65553388; called by muse, mutect2, varscan2
- ANK1 | c.3039C>T p.N1013= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs111620878; called by mutect2, varscan2
- APOB | c.9471C>A p.G3157= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as COSV51944060; called by muse, mutect2, varscan2
- ATIC | c.1728C>T p.D576= | Silent (SNP) | VAF 72/147 reads (49%) | catalogued as rs750485941, COSV52694313; called by muse, mutect2, varscan2
- CACNA1E | c.3792G>A p.R1264= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100702411; called by muse, mutect2
- CPED1 | c.384C>T p.I128= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs146930994; called by muse, mutect2, varscan2
- DVL3 | c.954A>G p.V318= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV57457240; called by muse, mutect2, varscan2
- FIGN | c.1407C>T p.I469= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs1361604870, COSV60769493; called by muse, mutect2, varscan2
- IGHV5-51 | c.291C>T p.T97= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs72686840; called by muse, mutect2, varscan2
- IRS2 | c.1782G>A p.S594= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1464161443, COSV101019075; called by muse, mutect2
- KANK3 | c.1683G>A p.R561= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- KRT37 | c.1134C>T p.A378= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as rs751478916, COSV56657018; called by muse, mutect2, varscan2
- KRTAP17-1 | c.129C>T p.C43= | Silent (SNP) | VAF 31/49 reads (63%) | catalogued as rs368577794, COSV61971934, COSV61972349; called by muse, varscan2
- MYO19 | c.1080G>A p.Q360= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- NCOR2 | c.2538C>T p.P846= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs532518067, COSV62300850; called by muse, mutect2, varscan2
- NYAP2 | c.1005G>A p.P335= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs1474403566, COSV56011117; called by muse, mutect2, varscan2
- OR5L1 | c.603G>T p.L201= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs150792242, COSV61734706; called by muse, mutect2, varscan2
- PCDHA3 | c.1389C>T p.F463= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as rs376590372; called by muse, mutect2, varscan2
- PPFIA4 | c.111G>A p.R37= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99829923; called by muse, mutect2, varscan2
- PSD2 | c.1902C>T p.A634= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs774122278, COSV51204449; called by muse, mutect2, varscan2
- RAPSN | c.258C>T p.Y86= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as CM044700, COSV54085147; called by muse, mutect2, varscan2
- RP1 | c.663G>A p.A221= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs745452078, COSV55119379; called by muse, mutect2, varscan2
- SEL1L2 | c.696A>G p.L232= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV53154953; called by muse, mutect2, varscan2
- SIM1 | c.450C>T p.F150= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs368515157; called by muse, mutect2, varscan2
- SOX17 | c.267G>A p.Q89= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV52027002, COSV52028714; called by muse, mutect2, varscan2
- TCHP | c.594G>A p.A198= | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as rs142930724, COSV100452567; called by muse, mutect2, varscan2
- TPRX1 | c.1122G>A p.Q374= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV59116639; called by muse, mutect2, varscan2
